Somatic mutation profile of tumor specimen TCGA-EY-A54A-01A (aliquot TCGA-EY-A54A-01A-11D-A27P-09) from TCGA case TCGA-EY-A54A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 68.0 years (24,822 days).
Specimen TCGA-EY-A54A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89707dba-c48d-4cea-b88b-b6f0178d3c3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A54A-10A (Blood Derived Normal), aliquot TCGA-EY-A54A-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54cf5b81-9b82-4e3b-a470-6717b7cb1fd5

The open-access MAF lists 116 somatic variants for this specimen: 90 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Frame Shift Del 6, Intron 3, Splice Site 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 2, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.4735G>A p.E1579K (on ENST00000366508; = p.E1553K on NM_015446.5) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100404032; called by muse, mutect2, varscan2
- AHNAK2 | c.2855T>G p.V952G | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100318151; called by muse, mutect2
- ARHGEF10L | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100769985; called by muse, mutect2
- ASXL1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs780662350, COSV60116087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEST3 | c.1210C>A p.H404N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100437847, COSV104401123; called by muse, mutect2, varscan2
- BMX | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV100564541; called by muse, mutect2, varscan2
- C5orf58 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV50458696; called by muse, mutect2, varscan2
- CALCRL | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101131004; called by muse, mutect2, varscan2
- CARD11 | c.3144+1G>A p.X1048_splice | Splice Site (SNP) | VAF 15/75 reads (20%) | catalogued as COSV67800432; called by muse, mutect2, varscan2
- CENPB | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.211); catalogued as COSV100713529; called by muse, varscan2
- CEP19 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99582547; called by muse, mutect2
- CEP250 | c.4519A>T p.R1507W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100699035; called by muse, mutect2
- CEP55 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV101017087; called by muse, mutect2, varscan2
- CHD4 | c.3382G>C p.V1128L (on ENST00000357008 / NM_001363606.2; = p.V1141L on NM_001273.5) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58898921; called by muse, mutect2, varscan2
- CLEC4M | c.936+2T>A p.X312_splice | Splice Site (SNP) | VAF 39/54 reads (72%) | catalogued as COSV99940677; called by muse, mutect2, varscan2
- COL24A1 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs762501445, COSV65310148; called by muse, mutect2, varscan2
- CPNE4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759688830, COSV101456761; called by muse, mutect2, varscan2
- DENND2B | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV100567619; called by muse, mutect2, varscan2
- DNAI4 | c.2496G>C p.R832= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as rs145354917, COSV100925492; called by muse, mutect2, varscan2
- EIF2S2 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV100894980, COSV66621437; called by muse, mutect2
- EPC1 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53925867; called by muse, mutect2, varscan2
- EXD1 | c.1179A>C p.Q393H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV100153735; called by muse, mutect2, varscan2
- F8 | c.5195G>T p.S1732I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV100811652; called by muse, mutect2, varscan2
- FOXRED2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.349); catalogued as COSV99341021; called by muse, mutect2, varscan2
- GCNA | c.1989C>G p.S663R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); catalogued as COSV101031674; called by muse, mutect2, varscan2
- GCNT1 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV100946596; called by muse, mutect2
- GRIK5 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99490901; called by muse, mutect2, varscan2
- GSPT2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100468231; called by muse, mutect2, varscan2
- GSTM2 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV53983086, COSV99598285; called by muse, mutect2, varscan2
- HPSE | c.1188A>C p.E396D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100264403; called by muse, mutect2, varscan2
- HTR1E | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs780937683, COSV59509592; called by muse, mutect2, varscan2
- IER5 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100849695; called by muse, mutect2, varscan2
- IL4R | c.2132T>A p.I711N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99405162; called by muse, mutect2
- INSRR | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100693541; called by muse, mutect2, varscan2
- ITIH6 | c.2958C>G p.I986M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV99513553; called by muse, mutect2, varscan2
- KCNMB2 | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100843982; called by muse, mutect2
- KDM2A | c.3248A>G p.N1083S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs754987680, COSV100445701; called by muse, mutect2, varscan2
- KRT12 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99289018; called by muse, mutect2
- LRRC2 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as rs769683488, COSV99947525; called by muse, mutect2, varscan2
- LZTR1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV99302022; called by muse, mutect2, varscan2
- MGA | c.7474C>T p.R2492W (on ENST00000219905 / NM_001164273.1; = p.R2283W on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1411818407, COSV54963139; called by muse, mutect2, varscan2
- MOAP1 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs748529958, COSV99365740; called by muse, mutect2, varscan2
- MOV10L1 | c.3183C>A p.S1061R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99434303; called by muse, mutect2, varscan2
- MRC2 | c.2652G>C p.E884D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.519); catalogued as COSV100316429; called by muse, mutect2, varscan2
- MYBPC3 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99920646; called by muse, varscan2
- MYO1E | c.971C>G p.T324R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs546799247; called by muse, mutect2, varscan2
- NEB | c.4605G>A p.M1535I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV99425019; called by muse, mutect2, varscan2
- NYAP1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs148577061; called by muse, mutect2, varscan2
- OR2T12 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs759597222, COSV100527873; called by muse, mutect2, varscan2
- PANK4 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1222462940, COSV65865839; called by muse, mutect2
- PCDH17 | c.16T>C p.C6R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100931761; called by muse, mutect2, varscan2
- POP1 | c.1526T>A p.V509D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100855974, COSV62894486; called by muse, mutect2, varscan2
- PPP1R15B | c.86C>G p.S29W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.161); catalogued as COSV100916350; called by muse, mutect2, varscan2
- PRPH | c.1152C>A p.N384K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV57678461, COSV99142026; called by muse, mutect2
- PRR19 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.082); catalogued as COSV100003970; called by muse, mutect2
- PUS7L | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.159); catalogued as COSV100786560; called by muse, mutect2, varscan2
- RGL1 | c.1182A>C p.K394N (on ENST00000360851 / NM_001297672.2; = p.K429N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100487139; called by mutect2, varscan2
- RIPK4 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 43/54 reads (80%) | catalogued as COSV100205117; called by muse, mutect2, varscan2
- RLF | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV101035530; called by muse, mutect2, varscan2
- RP1L1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV66757239; called by muse, mutect2, varscan2
- SCN9A | c.3887G>T p.R1296I (on ENST00000303354; = p.R1285I on NM_002977.3) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100313394; called by muse, mutect2, varscan2
- SCUBE1 | c.1152C>A p.Y384* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100683456; called by muse, mutect2
- SEPTIN14 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV101193381; called by muse, mutect2, varscan2
- SLC38A3 | c.1305C>T p.I435= | Splice Region (SNP) | VAF 25/42 reads (60%) | catalogued as rs587688203, COSV101309958; called by muse, mutect2, varscan2
- SLC44A5 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs1190292270, COSV63776281; called by muse, mutect2, varscan2
- SLC5A1 | c.1450-1G>T p.X484_splice | Splice Site (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99833555; called by muse, mutect2, varscan2
- SMAD2 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100053811; called by muse, mutect2, varscan2
- SYCP2 | c.4047G>A p.W1349* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100698344; called by muse, mutect2, varscan2
- TEX14 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1369588626, COSV99542714; called by muse, mutect2
- THRAP3 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV100663451; called by muse, mutect2, varscan2
- TIAF1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); catalogued as rs1284976004, COSV100572430; called by muse, mutect2
- TMEM236 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100592569; called by muse, mutect2, varscan2
- TP53 | c.938del p.S313Tfs*32 | Frame Shift Del (DEL) | VAF 53/95 reads (56%) | catalogued as COSV53728006; called by mutect2, pindel, varscan2
- TRMT11 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.97); catalogued as rs199550556, COSV100543244; called by muse, varscan2
- TTC12 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1409045911, COSV59096954; called by muse, mutect2, varscan2
- TTN | c.17646del p.T5883Pfs*6 (on ENST00000591111; = p.T4956Pfs*6 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs1321261103, COSV100596663; called by mutect2, varscan2
- UBA6 | c.2527C>A p.Q843K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV100451773; called by muse, mutect2
- UFL1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1562249506, COSV100990044; called by muse, mutect2
- YWHAH | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99963810; called by muse, mutect2, varscan2
- ZFP41 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV100414722, COSV58087950; called by muse, mutect2, varscan2
- ZNF223 | c.1241G>C p.S414T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV101462640; called by muse, mutect2
- ZNF836 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs750141578, COSV100441041; called by muse, mutect2, varscan2
- ARMH4 | c.156del p.D53Mfs*3 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- ATM | c.233del p.A78Efs*38 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- HNRNPR | c.1397_1414dup p.G466_Y471dup | In Frame Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- HTR2C | c.249dup p.L84Tfs*16 | Frame Shift Ins (INS) | VAF 23/65 reads (35%) | called by muse*, pindel
- KMT2D | c.6097_6100del p.Q2033Tfs*13 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by pindel, varscan2
- YLPM1 | c.867_868del p.P290Tfs*14 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- ZBTB22 | c.1582_1583dup p.T529* | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- ANAPC5 | c.804C>T p.F268= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99946323; called by muse, mutect2, varscan2
- ARMT1 | c.1296T>C p.Y432= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100939819; called by muse, mutect2, varscan2
- CLDN18 | c.159C>T p.C53= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs201156499, COSV51737798; called by muse, mutect2, varscan2
- CUBN | c.9027C>T p.I3009= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1324511563, COSV100913048; called by muse, mutect2, varscan2
- FOXS1 | c.375C>T p.G125= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99640016; called by muse, mutect2, varscan2
- GAD1 | c.1539C>A p.V513= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100827974; called by muse, mutect2, varscan2
- GPR155 | c.1062T>G p.S354= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99790024; called by muse, mutect2, varscan2
- LDB2 | c.537A>G p.Q179= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100454125; called by muse, mutect2
- NFAM1 | c.585G>A p.G195= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs1425331434, COSV100215964; called by muse, mutect2, varscan2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2, varscan2
- OR6C4 | c.639A>G p.T213= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV101263157, COSV67793171; called by muse, mutect2
- PDGFA | c.342C>T p.S114= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs761521449, COSV63280746; called by muse, mutect2, varscan2
- PELI3 | c.882C>T p.I294= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1217732383, COSV100291828; called by muse, mutect2, varscan2
- PPARG | c.192C>G p.P64= (on ENST00000287820 / NM_015869.5; = p.P34= on NM_005037.7) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99826614; called by muse, mutect2, varscan2
- PTGER4 | c.453C>T p.C151= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100201610; called by muse, mutect2
- SOGA3 | c.1728C>T p.A576= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1222937699, COSV100846979; called by muse, mutect2
- SYNCRIP | c.1141C>A p.R381= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100784175, COSV100784264, COSV62289354; called by mutect2, varscan2
- TAS2R10 | c.795C>T p.T265= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99555573; called by muse, mutect2, varscan2
- TNFSF4 | c.73T>C p.L25= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99919419; called by muse, mutect2
- VDR | c.984G>A p.E328= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1441257620, COSV99968488, COSV99968849; called by muse, mutect2, varscan2
- ZDHHC21 | c.258G>A p.R86= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as COSV101099560; called by muse, mutect2, varscan2
- ZNF479 | c.1389A>G p.R463= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100482445, COSV100482859; called by muse, mutect2
- AL645933.1 | chr6:31464061 C>G | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- EWSR1 | c.975-1104C>T | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100131799; called by muse, mutect2, varscan2
- NACA | c.71-2410C>A | Intron (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100771439; called by muse, mutect2, varscan2
- RCC1 | c.-228-84C>G | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100775650; called by muse, mutect2, varscan2
